Surgical pathology report (de-identified scan), TCGA case TCGA-DY-A0XA, project TCGA-READ (Rectum Adenocarcinoma), tissue source site University Of Michigan, specimen TCGA-DY-A0XA-01A (Primary Tumor).

TSS Patient ID: Sample Procurement: Date:
Gender: Date of Birth:
Vital Status: Date of Death:
Race: White Ethnicity: Not Hispanic or Latino Specific Ethnicity:
Histologic Subtype: Rectal adenocarcinoma Date of Initial Path Dx:
Primary Site: Colons Anatomic Site: Rectosigmoid Colon
T Stage: 3 N Stage: 0 M Stage: 0 Overall Stage: IIA
Date of Normal Procurement:

ICD-0-3
adenocarcinoma, NOS 8140/3
Site: Rectosigmoid colon C19.9

fw
6/11/12

Diagnostic Discrepancy		/
Case in (circle): QUALIFIED		

Source: NCI Genomic Data Commons file c68f4f2d-716e-4685-8d84-b7ca0fd169ba (TCGA-DY-A0XA.47B69AE9-9AA3-4B40-A574-96DA72155DEE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).